CCDI case PBCJAS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/bf47453d-565a-4a74-895c-024daaec9c71

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 10.8 years (3,951 days).

Biospecimens (3 samples)
- Sample 0DX4EP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4F3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX4FN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
